Somatic mutation profile of tumor specimen TCGA-L9-A8F4-01A (aliquot TCGA-L9-A8F4-01A-11D-A397-08) from TCGA case TCGA-L9-A8F4, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 64.7 years (23,617 days).
Specimen TCGA-L9-A8F4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 73608a3f-2456-4d89-a9d0-38bfbd8e0393.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L9-A8F4-10A (Blood Derived Normal), aliquot TCGA-L9-A8F4-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fcb7d2b1-add0-4e0c-8b76-db00bab3bd18

The open-access MAF lists 846 somatic variants for this specimen: 638 protein-altering or splice-affecting, 185 silent, 23 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 548, Silent 185, Nonsense Mutation 41, Splice Site 20, Frame Shift Del 16, RNA 10, Intron 8, Frame Shift Ins 5, Splice Region 4, 5'Flank 2, In Frame Del 2, 3'Flank 2.

Variants (750 of 846; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 19/61 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.4777G>T p.V1593L | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101330158; called by muse, mutect2, varscan2
- ABCA5 | c.2279T>C p.F760S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101201264; called by muse, mutect2
- ABCC11 | c.853T>A p.C285S | Missense Mutation (SNP) | VAF 33/151 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV100751090; called by muse, mutect2, varscan2
- ABCC2 | c.3415-1G>T p.X1139_splice | Splice Site (SNP) | VAF 11/50 reads (22%) | catalogued as COSV100966679; called by muse, mutect2, varscan2
- AC097636.1 | c.421C>G p.P141A | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV101469686, COSV71309698; called by muse, mutect2, varscan2
- AC100868.1 | c.1445G>T p.G482V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99031614; called by muse, mutect2, varscan2
- AC100868.1 | c.1444G>T p.G482W | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1305605407, COSV99226747; called by muse, mutect2, varscan2
- ACAD9 | c.901A>T p.N301Y | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1160209822, COSV100459389; called by muse, mutect2, varscan2
- ACADL | c.862C>A p.L288I | Missense Mutation (SNP) | VAF 30/81 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV99285023; called by muse, mutect2, varscan2
- ACE | c.1445G>C p.R482P | Missense Mutation (SNP) | VAF 32/127 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.034); catalogued as rs757694144, COSV52011166, COSV99327631; called by muse, mutect2, varscan2
- ACSM1 | c.982G>T p.D328Y | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV54634883, COSV99533353; called by muse, mutect2, varscan2
- ACSM2B | c.467C>A p.A156D | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100313062; called by muse, mutect2, varscan2
- ACTRT1 | c.58C>G p.L20V | Missense Mutation (SNP) | VAF 27/107 reads (25%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.814); catalogued as COSV100947729; called by muse, mutect2, varscan2
- ACVR1B | c.728C>A p.S243Y | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99231876; called by muse, mutect2, varscan2
- ADAM10 | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.887); catalogued as rs1243751725, COSV99546539; called by muse, mutect2, varscan2
- ADAMTS12 | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 63/140 reads (45%) | catalogued as rs866361455, COSV100711577; called by muse, mutect2, varscan2
- ADAMTS6 | c.3132G>T p.Q1044H | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.078); catalogued as COSV100068560; called by muse, mutect2, varscan2
- ADCY2 | c.790C>A p.L264M | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV100603823; called by muse, mutect2, varscan2
- ADCY5 | c.2109C>T p.D703= | Splice Region (SNP) | VAF 11/23 reads (48%) | catalogued as COSV100568172; called by muse, mutect2, varscan2
- ADCY7 | c.199G>T p.G67C | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV99576311, COSV99576398; called by muse, mutect2, varscan2
- ADGRB3 | c.2509C>T p.Q837* | Nonsense Mutation (SNP) | VAF 33/152 reads (22%) | catalogued as COSV99486598; called by muse, mutect2, varscan2
- ADGRG2 | c.2080T>A p.C694S (on ENST00000379869 / NM_001079858.3; = p.C691S on NM_005756.4) | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100492584; called by muse, mutect2, varscan2
- ADM | c.251G>T p.S84I | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.276); catalogued as COSV99534353; called by muse, mutect2, varscan2
- AFF2 | c.3592C>A p.Q1198K | Missense Mutation (SNP) | VAF 37/192 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); catalogued as COSV99665876; called by muse, mutect2, varscan2
- AGAP3 | c.988A>G p.K330E (on ENST00000622464; = p.K366E on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.164); catalogued as COSV58995635; called by muse, mutect2, varscan2
- AHCTF1 | c.1099A>G p.T367A (on ENST00000366508; = p.T341A on NM_015446.5) | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.488); catalogued as COSV100404319; called by muse, mutect2, varscan2
- AIFM1 | c.383C>A p.A128E | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.019); catalogued as rs763912966, COSV54852430, COSV99781391; called by muse, mutect2, varscan2
- AKAP13 | c.182G>A p.G61D | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100774431; called by muse, mutect2, varscan2
- AL121899.2 | c.1448C>A p.T483K | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.94); PolyPhen benign (0.011); catalogued as rs374109992, COSV101198632, COSV67351841; called by muse, mutect2, varscan2
- ALCAM | c.485G>T p.S162I | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV100065520; called by muse, mutect2, varscan2
- ALDH1L1 | c.1504G>T p.E502* | Nonsense Mutation (SNP) | VAF 14/53 reads (26%) | catalogued as COSV99857406; called by muse, mutect2, varscan2
- ALG3 | c.982G>C p.V328L | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV99891637; called by muse, varscan2
- ALK | c.1919G>T p.G640V | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as COSV101202595, COSV66561543; called by muse, mutect2, varscan2
- ANK2 | c.11773C>A p.Q3925K | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.375); catalogued as COSV100003755; called by muse, mutect2, varscan2
- ANKRD30A | c.2552G>T p.R851I (on ENST00000611781; = p.R795I on NM_052997.2) | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as rs1405837998, COSV100652884, COSV100653678; called by muse, mutect2
- ANKRD44 | c.2810A>G p.E937G | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.127); catalogued as COSV56555859, COSV99985863; called by muse, mutect2, varscan2
- ANXA6 | c.1197G>T p.Q399H | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100637079; called by muse, mutect2, varscan2
- APOL6 | c.710G>T p.G237V | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV101291015; called by muse, mutect2, varscan2
- ARHGAP31 | c.1224G>T p.E408D | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as COSV99957631; called by muse, mutect2, varscan2
- ARHGAP5 | c.1969G>T p.G657W | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100565662; called by muse, mutect2, varscan2
- ARHGAP6 | c.430G>T p.A144S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.001); catalogued as COSV100498980; called by muse, mutect2
- ARID1B | c.5212G>C p.D1738H | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.188); catalogued as COSV99271450; called by muse, mutect2
- ARRDC3 | c.622A>T p.I208F | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV54364400, COSV99475377; called by muse, mutect2, varscan2
- ASB15 | c.1339G>T p.D447Y | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); catalogued as COSV51923644, COSV99306921; called by muse, mutect2, varscan2
- ASB4 | c.1154T>A p.M385K | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV100367287; called by muse, mutect2, varscan2
- ASIC2 | c.1124T>A p.M375K | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99860933; called by muse, mutect2, varscan2
- ASXL1 | c.2230G>T p.G744* | Nonsense Mutation (SNP) | VAF 8/47 reads (17%) | catalogued as rs1311916988, COSV100040908; called by muse, mutect2, varscan2
- ASXL3 | c.2617G>A p.E873K | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.141); catalogued as COSV52468081; called by muse, mutect2, varscan2
- ATG13 | c.1499C>G p.A500G (on ENST00000359513 / NM_001346321.1; = p.A463G on NM_014741.4 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV100358028; called by muse, mutect2, varscan2
- ATP10B | c.3237G>T p.Q1079H | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100515642; called by muse, mutect2, varscan2
- ATP13A4 | c.3379-1G>T p.X1127_splice | Splice Site (SNP) | VAF 9/45 reads (20%) | catalogued as rs1462790714, COSV100710671; called by muse, mutect2
- ATP13A4 | c.2560G>T p.G854W | Missense Mutation (SNP) | VAF 31/199 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100710672; called by muse, mutect2, varscan2
- ATP1A2 | c.2913G>A p.M971I | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.045); catalogued as COSV63403571; called by muse, mutect2, varscan2
- ATP1A3 | c.2156G>A p.G719E (on ENST00000545399 / NM_001256214.2; = p.G706E on NM_152296.5) | Missense Mutation (SNP) | VAF 7/117 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100132501; called by muse, mutect2
- ATP1A4 | c.2266C>G p.L756V | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as COSV100927630; called by muse, mutect2, varscan2
- ATP6AP1 | c.809G>T p.W270L | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100870726; called by muse, mutect2, varscan2
- ATP6AP2 | c.847G>T p.A283S | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV65797474; called by muse, mutect2, varscan2
- ATP6AP2 | c.848C>T p.A283V | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV101011557; called by muse, mutect2, varscan2
- ATP6V1H | c.1385A>G p.H462R | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100778791; called by muse, mutect2, varscan2
- ATRX | c.7132G>A p.A2378T | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.471); catalogued as COSV100971319; called by muse, mutect2, varscan2
- ATRX | c.3334A>G p.T1112A | Missense Mutation (SNP) | VAF 21/264 reads (8%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as COSV64880047; called by muse, mutect2
- ATRX | c.493C>G p.L165V | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV100969621; called by muse, mutect2, varscan2
- ATXN2L | c.962G>T p.R321L | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as COSV100295046, COSV57370303; called by muse, mutect2, varscan2
- BCL11B | c.1689C>A p.S563R (on ENST00000357195 / NM_001282237.2; = p.S492R on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as COSV100595831; called by muse, mutect2
- BCL6 | c.1883A>G p.K628R | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99215983; called by muse, mutect2, varscan2
- BCLAF1 | c.410G>T p.R137M | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.753); catalogued as rs191698395, COSV100786905; called by muse, mutect2, varscan2
- BCOR | c.4777G>T p.D1593Y (on ENST00000378444 / NM_001123385.2; = p.D1559Y on NM_017745.6) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100653954; called by muse, mutect2, varscan2
- BCORL1 | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 20/97 reads (21%) | catalogued as COSV99499121, COSV99500505; called by muse, mutect2, varscan2
- BHMT | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 17/106 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99165499; called by muse, mutect2, varscan2
- BPIFB2 | c.327G>T p.E109D | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.327); catalogued as COSV99401623; called by muse, mutect2, varscan2
- BTN3A2 | c.832A>G p.T278A | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100709733; called by muse, mutect2, varscan2
- BTN3A2 | c.927G>C p.Q309H | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV100709734; called by muse, mutect2, varscan2
- C11orf24 | c.1121A>T p.D374V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV100422676; called by muse, mutect2, varscan2
- C16orf78 | c.785G>T p.S262I | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV100147924, COSV54555035; called by muse, mutect2, varscan2
- CAGE1 | c.671C>A p.P224Q (on ENST00000512086; = p.P88Q on NM_205864.3) | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99700066; called by muse, mutect2, varscan2
- CAND2 | c.2234G>T p.R745L (on ENST00000456430 / NM_001162499.2; = p.R652L on NM_012298.3) | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs755177838, COSV99929621, COSV99929636; called by muse, mutect2, varscan2
- CASP5 | c.413A>T p.Q138L | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as COSV99508021; called by muse, mutect2
- CASZ1 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as rs1305883727, COSV100682087; called by muse, mutect2
- CBFA2T2 | c.148C>T p.P50S | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV100656507; called by muse, mutect2, varscan2
- CCDC116 | c.538G>T p.A180S | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.21); PolyPhen benign (0.057); catalogued as COSV99488996; called by muse, mutect2, varscan2
- CCDC12 | c.298G>A p.E100K (on ENST00000425441 / NM_001277074.1; = p.E113K on NM_144716.5) | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.301); catalogued as rs749802375, COSV99439132; called by muse, mutect2
- CCDC180 | c.3553G>T p.A1185S | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.062); catalogued as COSV100827262; called by muse, mutect2, varscan2
- CCDC7 | c.2437C>A p.P813T | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.998); catalogued as COSV100179174; called by muse, mutect2
- CCNB3 | c.1993G>C p.A665P | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99329663; called by muse, mutect2, varscan2
- CDH15 | c.700G>A p.D234N | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1188416436, COSV99228432; called by muse, mutect2, varscan2
- CDH23 | c.7138C>A p.P2380T | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99823332; called by muse, mutect2
- CDH8 | c.830C>A p.A277E | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.042); catalogued as rs1289111612, COSV100183835; called by mutect2, varscan2
- CDH9 | c.570C>A p.N190K | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.145); catalogued as COSV99151415; called by muse, mutect2
- CDH9 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 45/225 reads (20%) | catalogued as COSV50419019; called by muse, mutect2, varscan2
- CERKL | c.818C>A p.A273D (on ENST00000339098 / NM_001030311.2; = p.A247D on NM_201548.5) | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100184092; called by muse, mutect2, varscan2
- CFAP47 | c.4822G>T p.G1608* | Nonsense Mutation (SNP) | VAF 9/81 reads (11%) | catalogued as COSV100545648; called by muse, mutect2, varscan2
- CFAP47 | c.4823G>T p.G1608V | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV100545649; called by muse, mutect2, varscan2
- CFAP92 | c.46G>T p.E16* | Nonsense Mutation (SNP) | VAF 8/33 reads (24%) | catalogued as COSV54047080, COSV99414890; called by muse, mutect2, varscan2
- CHRD | c.1154G>A p.W385* | Nonsense Mutation (SNP) | VAF 11/32 reads (34%) | catalogued as rs1315328760, COSV99200713; called by muse, mutect2, varscan2
- CHST1 | c.863T>C p.M288T | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV57324949; called by muse, mutect2, varscan2
- CLCN1 | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100578442; called by muse, mutect2, varscan2
- CLEC18B | c.740G>A p.C247Y | Missense Mutation (SNP) | VAF 15/165 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100376113; called by muse, mutect2, varscan2
- CLEC5A | c.323T>A p.I108N | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101407796; called by muse, mutect2, varscan2
- CMTM3 | c.311T>C p.L104P | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100726199; called by muse, mutect2, varscan2
- COL12A1 | c.8345T>C p.I2782T | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1318625044, COSV100486386; called by muse, mutect2, varscan2
- COL4A5 | c.4477C>A p.Q1493K | Missense Mutation (SNP) | VAF 35/183 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100089459; called by muse, mutect2, varscan2
- COL6A6 | c.2768C>A p.S923Y | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1269718570, COSV100650824, COSV62033278; called by muse, mutect2, varscan2
- COL8A1 | c.475A>G p.K159E | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as COSV53730245, COSV99658048; called by muse, mutect2
- COPS4 | c.178G>T p.V60L | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as rs768988116, COSV100018504, COSV100018801; called by muse, mutect2, varscan2
- CPLANE1 | c.9578G>T p.W3193L | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.011); catalogued as COSV99951501; called by muse, mutect2, varscan2
- CR1 | c.4004C>A p.T1335N | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.208); catalogued as rs777457095, COSV100887992; called by muse, mutect2, varscan2
- CSMD3 | c.8083C>T p.P2695S | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.21); catalogued as COSV99843289, COSV99845417; called by muse, mutect2, varscan2
- CTNNA2 | c.508C>A p.Q170K | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.585); catalogued as COSV100785748, COSV63544668; called by muse, mutect2, varscan2
- CTNNA2 | c.2275G>C p.A759P | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100561848; called by muse, mutect2, varscan2
- CUBN | c.3085G>A p.D1029N | Missense Mutation (SNP) | VAF 32/142 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs376195863; called by muse, mutect2, varscan2
- CXCL13 | c.64+1G>A p.X22_splice | Splice Site (SNP) | VAF 12/37 reads (32%) | catalogued as rs1489089184, COSV99724259; called by muse, mutect2, varscan2
- CXCR3 | c.25C>G p.Q9E | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as COSV101031721; called by muse, mutect2
- CXorf65 | c.541C>T p.Q181* | Nonsense Mutation (SNP) | VAF 9/64 reads (14%) | catalogued as COSV99340395; called by muse, mutect2, varscan2
- CYP1A2 | c.772C>A p.Q258K | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs775258473, COSV100673936; called by muse, mutect2, varscan2
- DACH1 | c.931G>T p.G311C | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as COSV100499065; called by muse, mutect2, varscan2
- DACH2 | c.380A>T p.Q127L | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100913790; called by muse, mutect2, varscan2
- DBR1 | c.1321G>T p.V441L | Missense Mutation (SNP) | VAF 51/146 reads (35%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV53430574; called by muse, mutect2, varscan2
- DCAF12L2 | c.485C>A p.T162K | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63580676, COSV63584176; called by muse, mutect2, varscan2
- DCAF4L2 | c.934G>T p.V312L | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.65); PolyPhen benign (0.219); catalogued as COSV100151237; called by muse, mutect2
- DCAF4L2 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 17/147 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100150917, COSV60481430; called by muse, mutect2, varscan2
- DELE1 | c.1309G>T p.A437S | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs1180400559, COSV99519992; called by muse, mutect2, varscan2
- DGCR8 | c.1133C>A p.P378H | Missense Mutation (SNP) | VAF 39/297 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as COSV100708142, COSV61228465; called by muse, mutect2, varscan2
- DHX34 | c.472G>T p.E158* | Nonsense Mutation (SNP) | VAF 18/58 reads (31%) | catalogued as COSV60896155; called by muse, mutect2, varscan2
- DHX38 | c.293A>T p.D98V | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV99194548; called by muse, mutect2
- DIAPH2 | c.1817C>A p.P606Q | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.601); catalogued as COSV100234791; called by muse, mutect2
- DIAPH2 | c.2418C>A p.H806Q | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV100234796; called by muse, mutect2, varscan2
- DLC1 | c.1065G>T p.M355I | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.878); catalogued as rs763562987, COSV52321300, COSV99365068; called by muse, mutect2, varscan2
- DLG3 | c.1078C>A p.P360T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.679); catalogued as COSV99530019; called by muse, mutect2, varscan2
- DLGAP4 | c.1742G>T p.S581I | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100211552; called by muse, mutect2, varscan2
- DMD | c.9785G>A p.S3262N | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100628957; called by muse, mutect2, varscan2
- DMGDH | c.2527A>T p.I843L | Missense Mutation (SNP) | VAF 23/152 reads (15%) | SIFT tolerated (0.76); PolyPhen benign (0.006); catalogued as COSV99669436; called by muse, mutect2, varscan2
- DMTN | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.054); catalogued as COSV99742101; called by muse, mutect2, varscan2
- DMXL2 | c.6262T>A p.C2088S | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV99198406; called by muse, mutect2
- DNER | c.1738A>C p.I580L | Missense Mutation (SNP) | VAF 24/110 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.053); catalogued as COSV100519893; called by muse, mutect2, varscan2
- DUSP21 | c.281C>A p.T94N | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as COSV100173659; called by muse, mutect2, varscan2
- DZIP3 | c.217A>T p.K73* | Nonsense Mutation (SNP) | VAF 23/111 reads (21%) | catalogued as COSV64311774; called by muse, mutect2, varscan2
- ECHDC1 | c.381G>T p.E127D (on ENST00000531967 / NM_001139510.1; = p.E121D on NM_018479.3) | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.062); catalogued as COSV100541883, COSV58932173; called by muse, mutect2, varscan2
- EDA2R | c.206G>T p.R69L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.32); catalogued as COSV99490922; called by muse, mutect2, varscan2
- EGFLAM | c.1176T>A p.F392L | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.018); catalogued as COSV100380683; called by muse, mutect2, varscan2
- EIF4G1 | c.3479G>C p.R1160P (on ENST00000346169 / NM_198241.3; = p.R965P on NM_004953.5) | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV100072234; called by muse, mutect2, varscan2
- EIF4G3 | c.4630G>A p.D1544N | Missense Mutation (SNP) | VAF 54/200 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV99945344; called by muse, mutect2, varscan2
- ELAPOR2 | c.2312G>T p.R771L (on ENST00000450689 / NM_001142749.3; = p.R604L on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.889); catalogued as COSV99789286; called by muse, mutect2, varscan2
- ENOX2 | c.1520C>A p.S507Y (on ENST00000338144 / NM_001382520.1; = p.S478Y on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.169); catalogued as COSV100584510; called by muse, mutect2, varscan2
- ENTPD5 | c.441+1G>A p.X147_splice | Splice Site (SNP) | VAF 8/125 reads (6%) | catalogued as COSV100592320; called by muse, mutect2
- EP300 | c.1882G>C p.E628Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV99609583; called by muse, mutect2, varscan2
- EPHB1 | c.2591A>G p.D864G | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV101214148; called by muse, mutect2
- EPHB1 | c.2794T>G p.F932V | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101214153; called by muse, mutect2
- EPRS1 | c.3145C>G p.L1049V | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV100859478, COSV65098296; called by muse, mutect2, varscan2
- EPS15 | c.2134G>T p.A712S | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.753); catalogued as COSV100869595; called by muse, mutect2
- ERICH3 | c.2927G>A p.G976E | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as rs1428015764, COSV100445435; called by muse, mutect2, varscan2
- ERLIN2 | c.589G>T p.A197S | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0.232); catalogued as COSV99379780; called by muse, mutect2, varscan2
- FAM135A | c.3827C>A p.P1276H (on ENST00000370479 / NM_001351599.1; = p.P1063H on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99526547; called by muse, mutect2
- FAM169A | c.1297G>A p.D433N | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.599); catalogued as COSV100769099; called by muse, mutect2, varscan2
- FAM199X | c.104G>C p.S35T | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.916); catalogued as COSV101534175; called by muse, mutect2, varscan2
- FAM47A | c.1369G>A p.E457K | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.044); catalogued as rs1479912221, COSV60496040; called by muse, mutect2, varscan2
- FAT1 | c.1817T>C p.I606T | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as rs1225154939, COSV101499607; called by muse, mutect2, varscan2
- FAT3 | c.2225G>T p.G742V | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1188907686, COSV99970168; called by muse, mutect2, varscan2
- FAT3 | c.6625A>T p.N2209Y | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53073218; called by muse, mutect2, varscan2
- FAT4 | c.10360G>T p.A3454S | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.556); catalogued as rs539311340, COSV100629861; called by muse, mutect2, varscan2
- FBLN1 | c.1267C>G p.L423V | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV99411311; called by muse, mutect2, varscan2
- FBN2 | c.7856A>T p.D2619V | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.163); catalogued as COSV99330160; called by muse, mutect2, varscan2
- FBXO38 | c.1176G>A p.M392I | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV99693871; called by muse, mutect2, varscan2
- FCRLA | c.725G>T p.R242M (on ENST00000367959; = p.R219M on NM_032738.4) | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.87); catalogued as COSV99376548; called by muse, mutect2, varscan2
- FER1L6 | c.144G>T p.L48F | Missense Mutation (SNP) | VAF 21/158 reads (13%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV101206143; called by muse, mutect2, varscan2
- FER1L6 | c.3985A>C p.K1329Q | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV101206144; called by muse, mutect2, varscan2
- FEZ1 | c.257C>A p.P86H | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99631052; called by muse, mutect2, varscan2
- FGD1 | c.1935+1G>T p.X645_splice | Splice Site (SNP) | VAF 3/12 reads (25%) | catalogued as COSV100911240; called by muse, mutect2
- FGD3 | c.1640C>T p.S547F | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100490840, COSV61596513; called by muse, mutect2, varscan2
- FHL5 | c.215G>A p.C72Y | Missense Mutation (SNP) | VAF 31/114 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1261907760, COSV100459702; called by muse, mutect2, varscan2
- FLG | c.1698T>A p.S566R | Missense Mutation (SNP) | VAF 79/461 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100912022; called by muse, mutect2, varscan2
- FMN2 | c.499G>T p.A167S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.321); catalogued as COSV60455692; called by muse, mutect2, varscan2
- FRG2C | c.803C>G p.T268S | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT tolerated, low confidence (0.44); PolyPhen probably damaging (0.953); catalogued as rs1199406797; called by muse, mutect2
- FRMPD4 | c.1398C>G p.H466Q | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.063); catalogued as COSV101043862; called by muse, mutect2, varscan2
- FSD1 | c.1036C>G p.L346V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV99696993; called by muse, mutect2, varscan2
- FYB1 | c.815G>T p.G272V | Missense Mutation (SNP) | VAF 47/141 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100686192; called by muse, mutect2, varscan2
- GABRA2 | c.324G>A p.M108I | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.38); PolyPhen benign (0.057); catalogued as COSV100734707, COSV62912152; called by muse, mutect2, varscan2
- GABRA5 | c.688C>A p.Q230K | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.405); catalogued as rs1266663568, COSV59480395; called by muse, mutect2
- GABRA6 | c.1184C>A p.P395H | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.524); catalogued as rs759522719, COSV99194914; called by muse, mutect2, varscan2
- GABRG1 | c.1271C>A p.T424K | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.04); catalogued as COSV54954254; called by muse, mutect2, varscan2
- GALNT17 | c.900G>A p.W300* | Nonsense Mutation (SNP) | VAF 15/74 reads (20%) | catalogued as COSV100355825; called by muse, mutect2, varscan2
- GAP43 | c.511C>A p.P171T | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100525898; called by muse, mutect2, varscan2
- GCNA | c.1487C>A p.P496H | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.208); catalogued as COSV101032659; called by muse, mutect2, varscan2
- GDE1 | c.487G>C p.E163Q | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as COSV62059213, COSV62059751; called by muse, mutect2, varscan2
- GDF5 | c.1236G>A p.M412I | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs1568731381, COSV100976952; called by muse, mutect2, varscan2
- GDF5 | c.490C>A p.P164T | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0.028); catalogued as COSV100976957; called by muse, mutect2, varscan2
- GDPD4 | c.450G>C p.K150N | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as COSV100265581; called by muse, mutect2, varscan2
- GIMAP1 | c.200C>A p.T67N | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as rs964759206, COSV100212274; called by muse, mutect2, varscan2
- GIMAP7 | c.437T>A p.I146K | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV100543759; called by muse, mutect2, varscan2
- GLI3 | c.720G>C p.Q240H | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.334); catalogued as COSV101230015, COSV67885404; called by muse, mutect2, varscan2
- GNAI1 | c.431G>T p.R144L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100650608; called by muse, mutect2, varscan2
- GNL1 | c.370G>T p.G124C | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100925444; called by muse, mutect2, varscan2
- GOLGA1 | c.1022C>G p.A341G | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.359); catalogued as COSV101001993; called by muse, mutect2
- GPA33 | c.619G>T p.G207C | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100901244; called by muse, mutect2, varscan2
- GPC2 | c.1664G>A p.G555E | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs1048208880, COSV99445035; called by muse, mutect2, varscan2
- GPR158 | c.395C>A p.A132D | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100894206; called by muse, mutect2, varscan2
- GPR161 | c.79A>T p.I27F | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs747924057, COSV99607105; called by muse, mutect2, varscan2
- GPR174 | c.650C>A p.P217H | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.852); catalogued as COSV52131792; called by muse, mutect2, varscan2
- GRB10 | c.862A>G p.S288G (on ENST00000398812; = p.S230G on NM_001001550.3) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV100240968; called by muse, mutect2, varscan2
- GRIK2 | c.337T>A p.S113T | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.513); catalogued as rs1456868168, COSV100028867; called by muse, mutect2, varscan2
- GRIN2B | c.3040C>A p.Q1014K | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.55); PolyPhen benign (0.013); catalogued as COSV101663167; called by muse, mutect2, varscan2
- GRIPAP1 | c.1411C>G p.R471G | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100904372; called by muse, mutect2, varscan2
- GRM8 | c.1131G>T p.R377S | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.017); catalogued as rs1325801158, COSV100285476; called by muse, mutect2, varscan2
- GRXCR1 | c.251C>G p.A84G | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.417); catalogued as COSV101295742; called by muse, mutect2, varscan2
- GTF3C4 | c.2351T>C p.I784T | Missense Mutation (SNP) | VAF 9/163 reads (6%) | SIFT tolerated (0.82); PolyPhen benign (0.007); catalogued as COSV100936073; called by muse, mutect2
- H2BW1 | c.450G>T p.M150I | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (1); PolyPhen probably damaging (0.946); catalogued as COSV99475144; called by muse, mutect2, varscan2
- H4C3 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100619626, COSV100619642; called by muse, mutect2, varscan2
- HAO1 | c.517A>T p.N173Y | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV101113301; called by muse, mutect2, varscan2
- HASPIN | c.829G>T p.V277L | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV99561466; called by muse, mutect2, varscan2
- HAVCR1 | c.434G>T p.R145L | Missense Mutation (SNP) | VAF 44/352 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs369837589, COSV100208555; called by muse, mutect2, varscan2
- HCN1 | c.662G>T p.W221L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV57501741, COSV57540654; called by muse, mutect2, varscan2
- HCRTR2 | c.132G>A p.W44* | Nonsense Mutation (SNP) | VAF 15/108 reads (14%) | catalogued as COSV100904573; called by muse, mutect2, varscan2
- HDAC6 | c.238G>T p.A80S | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100491209; called by muse, mutect2, varscan2
- HEBP2 | c.220C>G p.Q74E | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.006); catalogued as COSV100874954; called by muse, mutect2, varscan2
- HERC2 | c.680A>C p.E227A | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99876328; called by muse, mutect2
- HFM1 | c.3844A>G p.T1282A | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV99646658; called by muse, mutect2, varscan2
- HIVEP1 | c.4046C>T p.A1349V | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.611); catalogued as COSV101045643; called by muse, mutect2, varscan2
- HMBOX1 | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.09); catalogued as rs371243883; called by muse, mutect2, varscan2
- HOXA3 | c.1099G>T p.V367L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.988); catalogued as rs1430317144, COSV100415653, COSV57826640; called by muse, mutect2, varscan2
- HRNR | c.6257C>G p.S2086C | Missense Mutation (SNP) | VAF 12/252 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100913862; called by muse, mutect2
- HSPA12B | c.1997T>A p.V666D | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99422421; called by muse, mutect2
- HSPA8 | c.595G>T p.D199Y | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99914588, COSV99914622; called by muse, mutect2, varscan2
- HTR6 | c.906C>G p.F302L | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99230417; called by muse, mutect2, varscan2
- IGKV2-24 | c.6G>T p.R2S | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs779044707; called by muse, mutect2, varscan2
- IGSF10 | c.2650G>T p.G884C | Missense Mutation (SNP) | VAF 84/302 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV56788184, COSV99193041; called by muse, mutect2, varscan2
- IGSF11 | c.1058A>T p.N353I (on ENST00000393775 / NM_001015887.3; = p.N352I on NM_152538.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100677798; called by muse, mutect2, varscan2
- IGSF8 | c.112T>A p.Y38N | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100081811; called by muse, mutect2, varscan2
- IL21R | c.499T>A p.W167R | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV100560479, COSV61970352; called by muse, mutect2, varscan2
- IL23R | c.1423G>A p.V475I | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.789); catalogued as COSV100724899; called by muse, mutect2, varscan2
- INSR | c.1879G>T p.D627Y | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV100253237; called by muse, mutect2, varscan2
- IPO9 | c.2352G>C p.Q784H | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV100843541, COSV100843542; called by muse, mutect2, varscan2
- IQSEC2 | c.2947G>A p.D983N (on ENST00000642864 / NM_001111125.3; = p.D778N on NM_015075.2) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100945073; called by muse, mutect2, varscan2
- IRS4 | c.2978C>G p.A993G | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as COSV100929683; called by muse, mutect2, varscan2
- IRS4 | c.457T>A p.C153S | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100929686; called by muse, mutect2, varscan2
- ITIH5 | c.1757T>A p.L586Q | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.121); catalogued as COSV99905566; called by muse, mutect2
- ITIH6 | c.3385C>A p.P1129T | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772943801, COSV99513852; called by muse, mutect2, varscan2
- ITPR1 | c.5324G>T p.G1775V (on ENST00000354582; = p.G1720V on NM_002222.7) | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.046); catalogued as rs761431314, COSV100232885, COSV56984858; called by muse, mutect2, varscan2
- JMJD1C | c.6169T>C p.S2057P | Missense Mutation (SNP) | VAF 8/117 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.818); catalogued as COSV100550797; called by muse, mutect2
- KALRN | c.8902G>C p.V2968L (on ENST00000360013 / NM_001024660.4; = p.V1271L on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.026); catalogued as COSV99362779; called by muse, mutect2, varscan2
- KASH5 | c.1015C>A p.R339S | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs551444461, COSV101483493, COSV71358444; called by muse, mutect2, varscan2
- KATNIP | c.3110G>A p.G1037E | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746689639, COSV99851172, COSV99851836; called by muse, mutect2, varscan2
- KCNA1 | c.289C>A p.Q97K | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs1166033590, COSV101230326; called by muse, mutect2, varscan2
- KCNB2 | c.958G>A p.G320S | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV101578963; called by muse, mutect2, varscan2
- KCNG1 | c.656G>C p.R219T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV100857163; called by muse, mutect2, varscan2
- KCNK17 | c.358G>T p.G120C | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100950296; called by muse, mutect2, varscan2
- KCNMB2 | c.578C>A p.S193Y | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.781); catalogued as COSV100844020, COSV64201137; called by muse, mutect2
- KCNMB3 | c.506A>T p.N169I | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.522); catalogued as COSV99842614; called by muse, mutect2, varscan2
- KCNT2 | c.1440G>T p.M480I | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.012); catalogued as COSV99656269; called by muse, mutect2, varscan2
- KDM8 | c.278G>T p.R93L | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.268); catalogued as COSV99619922; called by muse, mutect2, varscan2
- KIF1B | c.2676-2A>G p.X892_splice (on ENST00000377086 / NM_001365952.1; = p.X846_splice on NM_015074.3) | Splice Site (SNP) | VAF 39/188 reads (21%) | catalogued as COSV99824043; called by muse, mutect2, varscan2
- KIF2C | c.1289A>T p.Q430L | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100945846; called by muse, mutect2
- KIRREL2 | c.841G>C p.D281H | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52877961, COSV99384367; called by muse, mutect2, varscan2
- KLHL10 | c.872C>A p.A291D | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV99509652; called by muse, mutect2, varscan2
- KLHL34 | c.991G>T p.E331* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | catalogued as COSV101069983; called by muse, mutect2
- KLHL4 | c.888T>A p.C296* | Nonsense Mutation (SNP) | VAF 10/61 reads (16%) | catalogued as COSV100910118; called by muse, mutect2, varscan2
- KLK4 | c.494T>G p.L165R | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100133700; called by muse, mutect2, varscan2
- KMT5C | c.734G>C p.R245T | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.035); catalogued as COSV99726314; called by muse, mutect2
- KPNA5 | c.809A>G p.D270G | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100706397; called by muse, mutect2
- KRT2 | c.196C>A p.L66I | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as COSV100548626; called by muse, mutect2, varscan2
- KRT6A | c.927G>T p.M309I | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.173); catalogued as rs966651416, COSV100417158; called by muse, mutect2
- KRT82 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 29/258 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs528794000, COSV99233757; called by muse, mutect2, varscan2
- KRT9 | c.652C>G p.L218V | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV99879342; called by muse, mutect2, varscan2
- KRTAP10-9 | c.823G>C p.V275L | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.48); catalogued as COSV100555238; called by muse, mutect2
- KRTAP6-3 | c.74G>T p.C25F | Missense Mutation (SNP) | VAF 14/67 reads (21%) | PolyPhen benign (0.059); catalogued as COSV101196513; called by muse, varscan2
- LEF1 | c.1081C>A p.Q361K | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.173); catalogued as COSV99489981; called by muse, mutect2, varscan2
- LGALS9C | c.720G>T p.K240N | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100055750; called by muse, mutect2, varscan2
- LHX8 | c.507G>T p.R169S | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99634274; called by muse, mutect2, varscan2
- LILRA1 | c.174C>A p.Y58* | Nonsense Mutation (SNP) | VAF 21/158 reads (13%) | catalogued as rs150949431; called by muse, mutect2, varscan2
- LILRA2 | c.156C>A p.S52R | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as COSV99253851; called by muse, mutect2, varscan2
- LILRB5 | c.1075G>C p.G359R | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100300729, COSV60260280; called by muse, mutect2, varscan2
- LMCD1 | c.560A>C p.K187T | Missense Mutation (SNP) | VAF 45/166 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV50088668, COSV99337807; called by muse, mutect2, varscan2
- LPA | c.4196C>A p.T1399K | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT tolerated (0.49); PolyPhen benign (0.111); catalogued as COSV100307902; called by muse, mutect2, varscan2
- LPCAT1 | c.900G>T p.E300D | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV99359310; called by muse, mutect2
- LRMDA | c.282G>C p.L94F | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.077); catalogued as COSV100995224; called by muse, mutect2
- LRP1B | c.13256C>T p.T4419I | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as rs765024477, COSV101259991; called by muse, mutect2, varscan2
- LRP1B | c.5612G>A p.R1871H | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.579); catalogued as rs757783196, COSV101259994; called by muse, mutect2, varscan2
- LRP1B | c.1971-2A>T p.X657_splice | Splice Site (SNP) | VAF 11/75 reads (15%) | catalogued as COSV101259995; called by muse, mutect2, varscan2
- LRRC27 | c.926+1G>C p.X309_splice | Splice Site (SNP) | VAF 34/128 reads (27%) | catalogued as COSV100689917; called by muse, mutect2, varscan2
- LRRC43 | c.1350-1G>A p.X450_splice | Splice Site (SNP) | VAF 12/64 reads (19%) | catalogued as COSV60293714; called by muse, mutect2, varscan2
- LRRFIP1 | c.1676C>G p.S559C | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as COSV100406293, COSV57826343; called by muse, mutect2
- LRRTM4 | c.1408G>T p.A470S | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs778362384, COSV101297704; called by muse, mutect2, varscan2
- LSG1 | c.1952G>T p.R651I | Missense Mutation (SNP) | VAF 30/234 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99503499; called by muse, varscan2
- LTB | c.196C>A p.Q66K | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.111); catalogued as rs1158677150, COSV100272340; called by muse, mutect2, varscan2
- LTF | c.953T>C p.L318P | Missense Mutation (SNP) | VAF 47/107 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99211011; called by muse, mutect2, varscan2
- LY75 | c.3454G>T p.V1152L | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as COSV99716919; called by muse, mutect2, varscan2
- LYPD2 | c.124A>T p.T42S | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.197); catalogued as COSV100821006; called by muse, mutect2, varscan2
- MAGEA6 | c.368A>T p.K123M | Missense Mutation (SNP) | VAF 41/228 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100262977; called by muse, mutect2, varscan2
- MAGEB3 | c.254G>C p.G85A | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.065); catalogued as COSV100854723, COSV100854793; called by muse, mutect2, varscan2
- MAGEC2 | c.380G>T p.C127F | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT tolerated (0.71); PolyPhen benign (0.02); catalogued as COSV56000314; called by muse, mutect2
- MAGEH1 | c.170C>A p.T57N | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.219); catalogued as COSV100746837; called by muse, mutect2, varscan2
- MAGT1 | c.582G>T p.L194F (on ENST00000618282 / NM_001367916.1; = p.L226F on NM_032121.5) | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.35); catalogued as COSV100800411; called by muse, mutect2, varscan2
- MAP2 | c.4075G>A p.V1359I | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.69); PolyPhen benign (0.012); catalogued as COSV99561484; called by muse, mutect2, varscan2
- MAP7 | c.593G>C p.R198P | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100644004; called by muse, mutect2, varscan2
- MAPK3 | c.642G>T p.E214D | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99531966; called by muse, mutect2, varscan2
- MARCHF8 | c.362G>T p.R121L | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100166019, COSV100166115, COSV60572107; called by muse, mutect2, varscan2
- MARK1 | c.104G>A p.S35N | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as COSV100857513; called by muse, mutect2, varscan2
- MAS1L | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV65808523, COSV65809359; called by muse, mutect2, varscan2
- MAS1L | c.696T>A p.H232Q | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV101009719, COSV65808968; called by muse, mutect2, varscan2
- MCMDC2 | c.602G>T p.G201V | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100552259; called by muse, mutect2, varscan2
- MCOLN2 | c.868G>A p.V290I | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1406991148, COSV99394184; called by muse, mutect2
- MED24 | c.2914G>T p.D972Y | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as rs1400292966, COSV99842530; called by muse, mutect2, varscan2
- METTL3 | c.1235A>T p.D412V | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV99398548; called by muse, mutect2, varscan2
- MRE11 | c.1099-1G>T p.X367_splice | Splice Site (SNP) | VAF 21/77 reads (27%) | catalogued as COSV100119998; called by muse, mutect2, varscan2
- MROH2B | c.3331C>A p.P1111T | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV101270887; called by muse, mutect2
- MRPS22 | c.401G>T p.R134L (on ENST00000310776 / NM_001363893.1; = p.R135L on NM_020191.4) | Missense Mutation (SNP) | VAF 13/108 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs774237195, COSV100169202, COSV60350598; called by muse, mutect2, varscan2
- MSC | c.63C>A p.Y21* | Nonsense Mutation (SNP) | VAF 8/43 reads (19%) | catalogued as COSV100335873; called by muse, mutect2, varscan2
- MSH6 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as rs763104308, COSV52274659, COSV99316759; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MTIF2 | c.99G>T p.W33C | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV99709313; called by muse, mutect2, varscan2
- MTIF2 | c.98G>A p.W33* | Nonsense Mutation (SNP) | VAF 29/132 reads (22%) | catalogued as COSV99709316; called by muse, mutect2, varscan2
- MTMR11 | c.908T>A p.V303E (on ENST00000439741 / NM_001145862.2; = p.V231E on NM_181873.3) | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100809256; called by muse, mutect2, varscan2
- MTOR | c.1828T>C p.F610L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.22); catalogued as COSV100816612, COSV63879033; called by muse, mutect2
- MUC16 | c.26694G>C p.L8898F | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.8); catalogued as COSV101201216; called by muse, mutect2, varscan2
- MUC16 | c.2158A>G p.I720V | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.02); catalogued as COSV101201217; called by muse, mutect2, varscan2
- MUC3A | c.422C>A p.P141H | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious, low confidence (0); catalogued as COSV100115261; called by muse, mutect2, varscan2
- MUC4 | c.1059A>C p.L353F | Missense Mutation (SNP) | VAF 9/195 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.598); catalogued as COSV100642087; called by muse, mutect2
- MXRA5 | c.4202G>T p.G1401V | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs1352311481, COSV99478858; called by muse, mutect2, varscan2
- MXRA5 | c.3248C>A p.S1083Y | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.086); catalogued as COSV99478860; called by muse, mutect2, varscan2
- MXRA5 | c.1272G>T p.Q424H | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV99478866; called by muse, mutect2, varscan2
- MXRA5 | c.934C>A p.Q312K | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV99478871; called by muse, mutect2, varscan2
- MYCBP2 | c.6445G>C p.E2149Q (on ENST00000357337; = p.E2187Q on NM_015057.5) | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100631560; called by muse, mutect2, varscan2
- MYH14 | c.5737G>T p.A1913S | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.206); catalogued as rs1045789246, COSV99223864; called by muse, mutect2
- MYH4 | c.2786G>A p.R929K | Missense Mutation (SNP) | VAF 74/218 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.053); catalogued as COSV55121113, COSV99702066; called by muse, mutect2, varscan2
- MYH6 | c.3505C>A p.R1169S | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100676932; called by muse, varscan2
- MYO10 | c.3443G>T p.S1148I | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99946126; called by muse, mutect2, varscan2
- MYOM3 | c.689T>C p.V230A | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.95); PolyPhen possibly damaging (0.773); catalogued as COSV100293668; called by muse, mutect2, varscan2
- NAPRT | c.682C>A p.P228T | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0.115); catalogued as rs761620110, COSV99435445; called by muse, mutect2, varscan2
- NBEA | c.519G>T p.M173I | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV100083463, COSV59807156; called by muse, mutect2
- NCAM2 | c.1981G>T p.G661W | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs748814453, COSV99521312; called by muse, mutect2, varscan2
- NCOA6 | c.5963A>T p.E1988V | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.404); catalogued as COSV100750278; called by muse, mutect2, varscan2
- NCR1 | c.865A>G p.R289G | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as COSV99401133; called by muse, mutect2, varscan2
- NDST4 | c.218C>G p.T73R | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.015); catalogued as COSV99995360, COSV99997632; called by muse, mutect2, varscan2
- NEDD4 | c.2285T>A p.L762H (on ENST00000508342 / NM_001284338.1; = p.L343H on NM_006154.4) | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV100164043; called by muse, mutect2, varscan2
- NEXN | c.686T>C p.M229T | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as COSV53942349; called by muse, mutect2, varscan2
- NFATC1 | c.2020G>T p.V674F | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99500374, COSV99502375; called by muse, mutect2, varscan2
- NFKBIZ | c.630G>T p.Q210H | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as COSV100397203; called by muse, mutect2, varscan2
- NHP2 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1214412834, COSV99200954; called by muse, mutect2
- NIPBL | c.4729G>T p.E1577* | Nonsense Mutation (SNP) | VAF 10/74 reads (14%) | catalogued as COSV56942510, COSV56965620; called by muse, mutect2, varscan2
- NIPBL | c.6824G>C p.S2275T | Missense Mutation (SNP) | VAF 20/180 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as COSV99242297; called by muse, mutect2, varscan2
- NKAP | c.251C>A p.P84H | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV101004283; called by muse, mutect2, varscan2
- NLRP2 | c.3023G>A p.C1008Y | Missense Mutation (SNP) | VAF 33/178 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs769085492, COSV99672589; called by muse, mutect2, varscan2
- NLRP3 | c.2140T>A p.C714S | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100276542; called by muse, mutect2, varscan2
- NME7 | c.535G>T p.A179S | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.088); catalogued as COSV100891145; called by muse, mutect2, varscan2
- NMNAT2 | c.654G>A p.M218I | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.086); catalogued as COSV54268294; called by muse, mutect2
- NOD2 | c.1139G>T p.G380V | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100318830; called by muse, mutect2, varscan2
- NOTCH1 | c.1858G>T p.D620Y | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53084858; called by muse, mutect2, varscan2
- NPAP1 | c.512G>A p.G171E | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.385); catalogued as COSV61504941; called by muse, mutect2, varscan2
- NPAS4 | c.1669C>A p.P557T | Missense Mutation (SNP) | VAF 30/175 reads (17%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as COSV100215205, COSV60651941; called by muse, mutect2, varscan2
- NPSR1 | c.943A>C p.I315L | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV100707041; called by muse, mutect2, varscan2
- NRAP | c.2575G>T p.E859* (on ENST00000359988 / NM_001322945.2; = p.E824* on NM_006175.4) | Nonsense Mutation (SNP) | VAF 15/57 reads (26%) | catalogued as COSV100748572; called by muse, mutect2, varscan2
- NRXN3 | c.1928G>T p.S643I (on ENST00000335750 / NM_001330195.2; = p.S270I on NM_004796.6) | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.348); catalogued as COSV100208094; called by muse, mutect2, varscan2
- NSUN3 | c.1023A>G p.*341Wext*16 | Nonstop Mutation (SNP) | VAF 9/78 reads (12%) | catalogued as COSV100113441; called by muse, mutect2
- NUBPL | c.818A>G p.D273G | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.328); catalogued as rs750832969, COSV99810200; called by muse, mutect2, varscan2
- OLFML2B | c.1891C>A p.L631I | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.145); catalogued as COSV99668816; called by muse, mutect2, varscan2
- OPRD1 | c.584C>A p.A195E | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.69); PolyPhen benign (0.216); catalogued as COSV99330501; called by muse, mutect2, varscan2
- OR10J3 | c.421G>T p.A141S | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as COSV100171858; called by muse, mutect2, varscan2
- OR10J3 | c.420G>T p.R140S | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.034); catalogued as COSV100171859; called by muse, mutect2, varscan2
- OR11H1 | c.728C>G p.S243C | Missense Mutation (SNP) | VAF 52/187 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV99421594, COSV99421966; called by muse, mutect2, varscan2
- OR11H12 | c.5G>C p.C2S | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); catalogued as COSV101612521; called by mutect2, varscan2
- OR14K1 | c.291G>T p.L97F | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as COSV99315421; called by muse, mutect2, varscan2
- OR1I1 | c.860C>G p.P287R | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52917363, COSV99264895; called by muse, mutect2, varscan2
- OR2G3 | c.320T>A p.L107Q | Missense Mutation (SNP) | VAF 28/205 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100180734; called by muse, mutect2, varscan2
- OR2M2 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 77/290 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1345382603, COSV100677306; called by muse, mutect2, varscan2
- OR2T33 | c.256G>T p.G86* | Nonsense Mutation (SNP) | VAF 29/198 reads (15%) | catalogued as COSV100532243; called by muse, mutect2, varscan2
- OR2W3 | c.538G>C p.E180Q | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100831813, COSV64457805; called by muse, mutect2, varscan2
- OR4C13 | c.119A>G p.N40S | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as rs1555015682, COSV101634227; called by muse, mutect2, varscan2
- OR4K15 | c.919A>T p.N307Y (on ENST00000305051; = p.N283Y on NM_001005486.1) | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100521134; called by muse, mutect2, varscan2
- OR51G1 | c.394C>A p.L132M | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100429377, COSV58968300; called by muse, mutect2, varscan2
- OR5K1 | c.267C>G p.N89K | Missense Mutation (SNP) | VAF 44/239 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.06); catalogued as COSV100221017; called by muse, mutect2, varscan2
- OR5M11 | c.509C>A p.S170Y | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV101602063; called by muse, mutect2, varscan2
- OR5P3 | c.371T>A p.V124E | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as COSV100103257; called by muse, mutect2, varscan2
- OR6F1 | c.227C>A p.A76E | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV57467743; called by muse, mutect2, varscan2
- OR6Y1 | c.947G>T p.G316V | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV56930308; called by muse, mutect2, varscan2
- OR7A17 | c.106C>A p.L36M | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.95); catalogued as COSV100541685; called by muse, mutect2, varscan2
- ORAI3 | c.575G>T p.R192L | Missense Mutation (SNP) | VAF 77/361 reads (21%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); catalogued as COSV99353593; called by muse, mutect2, varscan2
- OTOA | c.194C>A p.T65K | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs140152105, COSV99625617; called by muse, mutect2, varscan2
- OTULIN | c.533A>G p.D178G | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs779135276, COSV99420006; called by muse, mutect2
- OVCH1 | c.482C>A p.P161H | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100549099; called by muse, mutect2, varscan2
- OXCT1 | c.1436A>G p.D479G | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.185); catalogued as COSV99542075; called by muse, mutect2
- OXR1 | c.2577G>C p.K859N (on ENST00000442977 / NM_001198532.1; = p.K831N on NM_018002.3) | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99861204; called by muse, mutect2, varscan2
- PAQR5 | c.554G>T p.R185L | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100575596; called by muse, mutect2, varscan2
- PATE1 | c.176A>G p.K59R | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV59824156; called by muse, mutect2
- PCDH9 | c.634A>T p.R212* | Nonsense Mutation (SNP) | VAF 31/122 reads (25%) | catalogued as COSV100122973; called by muse, mutect2, varscan2
- PCDHA13 | c.2341G>T p.G781C | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.214); catalogued as COSV99169379; called by muse, mutect2
- PCDHA2 | c.1074del p.I359Sfs*31 | Frame Shift Del (DEL) | VAF 9/54 reads (17%) | catalogued as COSV100973801, COSV65366979; called by mutect2, pindel, varscan2
- PCDHA6 | c.610G>T p.E204* | Nonsense Mutation (SNP) | VAF 13/76 reads (17%) | catalogued as COSV100972505; called by muse, mutect2, varscan2
- PCDHGA7 | c.1966G>T p.A656S | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.536); catalogued as COSV99545383; called by muse, mutect2, varscan2
- PCK1 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs762530982, COSV100100842; called by muse, mutect2
- PCLO | c.6742G>T p.D2248Y | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.329); catalogued as COSV100436782; called by muse, mutect2, varscan2
- PCNX1 | c.3559G>T p.D1187Y | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1244305605, COSV99456951; called by muse, mutect2, varscan2
- PDE11A | c.2554A>T p.T852S | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.302); catalogued as rs1318913391, COSV99614450; called by muse, mutect2, varscan2
- PDK4 | c.982G>T p.A328S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as rs1412879351, COSV99138941; called by muse, mutect2
- PENK | c.612A>T p.K204N | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.478); catalogued as COSV100152452, COSV59241032; called by muse, mutect2, varscan2
- PGAP1 | c.2565G>T p.L855F | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.67); catalogued as rs1157034831, COSV61328765; called by muse, mutect2, varscan2
- PGK1 | c.641+1G>T p.X214_splice | Splice Site (SNP) | VAF 24/144 reads (17%) | catalogued as COSV100965345, COSV100965366; called by muse, mutect2, varscan2
- PHKA1 | c.52G>A p.V18M | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs971555820, COSV100263808; called by muse, mutect2, varscan2
- PIAS2 | c.1427G>T p.S476I | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100245504; called by muse, mutect2, varscan2
- PIK3C2G | c.1832A>T p.N611I (on ENST00000676171; = p.N570I on NM_004570.5) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.332); catalogued as COSV99853623; called by muse, mutect2
- PIK3CG | c.529C>G p.R177G | Missense Mutation (SNP) | VAF 5/44 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100783114, COSV63245916; called by muse, mutect2, varscan2
- PIK3R6 | c.1705A>G p.K569E | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.6); catalogued as COSV100266812; called by muse, mutect2, varscan2
- PJA1 | c.1276G>C p.G426R (on ENST00000361478 / NM_145119.4; = p.G238R on NM_022368.5) | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.07); catalogued as COSV100824795, COSV64053977; called by muse, mutect2, varscan2
- PKHD1 | c.3082A>G p.R1028G | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.173); catalogued as COSV100584332; called by muse, mutect2
- PKHD1 | c.1296G>C p.R432S | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.007); catalogued as COSV100584334, COSV61885972; called by muse, mutect2
- PKHD1L1 | c.6244C>T p.P2082S | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.009); catalogued as COSV65742548; called by muse, mutect2, varscan2
- PKHD1L1 | c.8707G>T p.V2903L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.04); catalogued as COSV101006719; called by muse, mutect2, varscan2
- PLD1 | c.1633G>C p.D545H | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.264); catalogued as COSV100578726, COSV60568208; called by muse, mutect2, varscan2
- PLXNA1 | c.917G>T p.G306V | Missense Mutation (SNP) | VAF 74/237 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1211113390, COSV99303948; called by muse, mutect2, varscan2
- PLXNA2 | c.5290G>T p.G1764C | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100885768; called by muse, mutect2, varscan2
- PLXNB2 | c.4297G>A p.E1433K | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100834262; called by muse, mutect2, varscan2
- PLXNB2 | c.3493G>A p.D1165N | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs1269542800, COSV63780998; called by muse, mutect2, varscan2
- PMPCB | c.1159C>T p.R387* | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | catalogued as rs756239393, COSV99971409; called by mutect2, varscan2
- PNLDC1 | c.1392G>C p.K464N | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.025); catalogued as COSV99277804; called by muse, mutect2
- PPM1D | c.1017+1G>T p.X339_splice | Splice Site (SNP) | VAF 6/44 reads (14%) | catalogued as COSV100011112; called by muse, mutect2, varscan2
- PPM1E | c.2188T>A p.Y730N | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.079); catalogued as COSV100376570; called by muse, mutect2, varscan2
- PPP2R1A | c.1685C>A p.P562H | Missense Mutation (SNP) | VAF 12/113 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV100436445; called by muse, mutect2, varscan2
- PREB | c.935G>T p.G312V | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99574768; called by muse, mutect2, varscan2
- PREB | c.934G>T p.G312C | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53208439, COSV99574771; called by muse, mutect2, varscan2
- PRKCB | c.1174C>T p.R392W | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100331765, COSV100332253; called by muse, mutect2, varscan2
- PRKCG | c.641C>A p.T214K | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as COSV54724087, COSV99669453; called by muse, mutect2, varscan2
- PROX1 | c.266G>T p.G89V | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99800100; called by muse, mutect2, varscan2
- PRRC1 | c.1211T>A p.L404* | Nonsense Mutation (SNP) | VAF 15/58 reads (26%) | catalogued as COSV99688101; called by muse, mutect2, varscan2
- PRRC2A | c.460G>C p.D154H | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100784623; called by muse, mutect2, varscan2
- PRSS55 | c.327C>A p.C109* | Nonsense Mutation (SNP) | VAF 50/183 reads (27%) | catalogued as COSV100153868; called by muse, mutect2, varscan2
- PSG9 | c.848G>T p.S283I | Missense Mutation (SNP) | VAF 65/159 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99392529; called by muse, mutect2, varscan2
- PTCHD3 | c.886T>A p.Y296N | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.747); catalogued as COSV101438960; called by muse, mutect2, varscan2
- PTER | c.836G>T p.R279I | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.102); catalogued as rs1242855883, COSV100126812; called by muse, mutect2
- PTPN13 | c.1431G>C p.E477D | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.129); catalogued as COSV100365327; called by muse, mutect2, varscan2
- PTPRD | c.5441C>A p.P1814Q | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100646432; called by muse, mutect2, varscan2
- PUS10 | c.1281A>T p.K427N | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.24); PolyPhen benign (0.019); catalogued as COSV100369720; called by muse, mutect2, varscan2
- QSER1 | c.3G>A p.M1? (on ENST00000399302; = p.M130I on NM_001076786.3) | Translation Start Site (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.048); catalogued as COSV101234954; called by mutect2, varscan2
- RALY | c.785C>A p.T262K (on ENST00000246194 / NM_016732.3; = p.T246K on NM_007367.4) | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.177); catalogued as COSV99866126; called by muse, varscan2
- RBL2 | c.2090G>T p.R697L | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.366); catalogued as COSV100044000, COSV50873099; called by muse, mutect2
- RBP3 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.959); catalogued as rs201653073; called by muse, mutect2, varscan2
- RBP3 | c.1015G>T p.D339Y | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1555211108; called by muse, mutect2, varscan2
- RFPL4B | c.388C>A p.P130T | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as COSV101480723, COSV71437143; called by muse, mutect2, varscan2
- RHOBTB1 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0.044); catalogued as COSV61959961; called by muse, mutect2, varscan2
- RIMS2 | c.2224C>A p.H742N (on ENST00000666250 / NM_001348490.2; = p.H550N on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99192548; called by muse, mutect2, varscan2
- RNF17 | c.3068G>A p.R1023K | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.72); PolyPhen benign (0.253); catalogued as rs1386434225, COSV99694234; called by muse, mutect2, varscan2
- RNLS | c.1004T>C p.L335P | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as rs544985084, COSV100076974; called by muse, mutect2, varscan2
- RPL8 | c.758A>T p.Q253L | Missense Mutation (SNP) | VAF 57/250 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.021); catalogued as COSV99369966; called by muse, mutect2, varscan2
- RPTN | c.742C>A p.Q248K | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.321); catalogued as COSV100285703; called by muse, mutect2, varscan2
- RUNX2 | c.952A>T p.T318S | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.784); catalogued as COSV100767719; called by muse, mutect2, varscan2
- RUSC2 | c.3298A>T p.S1100C | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100770847; called by muse, mutect2, varscan2
- RXRG | c.1006A>T p.S336C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100717805; called by muse, mutect2
- RYR1 | c.3656A>T p.Q1219L | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as CM118673, COSV100616763; called by muse, mutect2, varscan2
- RYR1 | c.4479G>T p.M1493I | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.78); catalogued as rs1377024045, COSV100616764; called by muse, mutect2, varscan2
- RYR2 | c.3702G>T p.E1234D | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV100772446, COSV63708479; called by muse, mutect2, varscan2
- RYR2 | c.6047C>T p.S2016F | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as rs1304117296, COSV100772447; called by muse, mutect2, varscan2
- RYR3 | c.11059C>A p.Q3687K (on ENST00000389232; = p.Q3688K on NM_001036.6) | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.328); catalogued as rs1172514084, COSV101214089, COSV66792732; called by muse, mutect2, varscan2
- SAGE1 | c.1597C>G p.Q533E | Missense Mutation (SNP) | VAF 19/143 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV100187795; called by muse, mutect2, varscan2
- SAMD7 | c.1088C>A p.T363K | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1269324567, COSV100157059; called by muse, mutect2, varscan2
- SASS6 | c.787G>T p.D263Y | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs1206412139, COSV99791043; called by muse, mutect2, varscan2
- SCARF2 | c.2524C>T p.P842S | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.625); catalogued as rs1012115551, COSV56731251; called by muse, mutect2
- SCCPDH | c.512A>G p.N171S | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.005); catalogued as COSV100829743; called by muse, mutect2, varscan2
- SCN5A | c.4744C>A p.L1582M (on ENST00000333535 / NM_198056.3; = p.L1581M on NM_000335.5) | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100350178; called by muse, mutect2, varscan2
- SCN5A | c.3115C>A p.P1039T | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.253); catalogued as COSV100350179; called by muse, mutect2
- SEMA3C | c.2199G>T p.K733N | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99543728; called by muse, mutect2, varscan2
- SFRP5 | c.407C>G p.A136G | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as COSV99823258; called by muse, mutect2, varscan2
- SGO1 | c.1198G>T p.V400F | Missense Mutation (SNP) | VAF 52/153 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); catalogued as COSV99768451; called by muse, mutect2, varscan2
- SI | c.428T>A p.I143N | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV100016861, COSV52270368; called by muse, mutect2, varscan2
- SIGLEC1 | c.447G>T p.E149D | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.37); PolyPhen benign (0.022); catalogued as COSV99170371; called by muse, mutect2, varscan2
- SIGLEC6 | c.1298A>T p.K433M | Missense Mutation (SNP) | VAF 43/220 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.846); catalogued as COSV100585634; called by muse, mutect2, varscan2
- SIN3A | c.64G>T p.G22C | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.241); catalogued as COSV99062930; called by muse, mutect2, varscan2
- SLC12A2 | c.2885T>A p.L962* | Nonsense Mutation (SNP) | VAF 11/75 reads (15%) | catalogued as COSV99321475; called by muse, mutect2, varscan2
- SLC12A5 | c.2354G>T p.G785V (on ENST00000454036 / NM_001134771.2; = p.G762V on NM_020708.5) | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1295554853, COSV99716649; called by muse, mutect2, varscan2
- SLC17A3 | c.641G>C p.R214T | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as COSV100399375, COSV57760079; called by muse, mutect2, varscan2
- SLC26A7 | c.370C>A p.Q124K | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV99404199; called by muse, mutect2, varscan2
- SLC44A5 | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV100902493; called by muse, mutect2, varscan2
- SLC47A2 | c.949+1G>C p.X317_splice | Splice Site (SNP) | VAF 18/52 reads (35%) | catalogued as COSV100328221; called by muse, mutect2
- SLC4A11 | c.1085C>T p.T362I | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs868600314, COSV101196122; called by muse, mutect2
- SLC4A1AP | c.46T>C p.S16P | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV100389598; called by muse, mutect2
- SLC5A11 | c.1004C>A p.P335Q | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100762811, COSV100762890; called by muse, mutect2, varscan2
- SLC6A15 | c.1801G>A p.A601T | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as rs376347410; called by muse, mutect2, varscan2
- SLC6A16 | c.919G>T p.G307C | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs371386937, COSV100242922; called by muse, varscan2
- SLC6A2 | c.786G>C p.V262= | Splice Region (SNP) | VAF 11/53 reads (21%) | catalogued as COSV99574472; called by muse, mutect2, varscan2
- SLC6A5 | c.772G>T p.G258* | Nonsense Mutation (SNP) | VAF 8/25 reads (32%) | catalogued as COSV100116875; called by muse, mutect2, varscan2
- SLCO6A1 | c.1150G>T p.V384L | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.021); catalogued as COSV101134884; called by muse, mutect2
- SLIT1 | c.2060G>T p.R687L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99821481, COSV99822321; called by muse, mutect2, varscan2
- SLIT1 | c.1142A>T p.Y381F | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as COSV56589995, COSV99822324; called by muse, mutect2, varscan2
- SMARCA1 | c.2286C>A p.Y762* | Nonsense Mutation (SNP) | VAF 10/55 reads (18%) | catalogued as COSV100946680; called by muse, mutect2, varscan2
- SNRPA | c.708G>C p.E236D | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV99698941; called by muse, mutect2, varscan2
- SORCS1 | c.1919G>A p.G640E | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.62); catalogued as COSV53842856, COSV99549674; called by muse, mutect2, varscan2
- SOX17 | c.282C>A p.H94Q | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99810808; called by muse, mutect2
- SPACA1 | c.680T>C p.V227A | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.64); catalogued as rs1252890554, COSV99389747; called by muse, mutect2, varscan2
- SPATA16 | c.1531G>C p.D511H | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100651555; called by muse, mutect2, varscan2
- SPATA7 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1301293262, COSV99248302; called by muse, mutect2, varscan2
- SPG7 | c.577G>T p.E193* | Nonsense Mutation (SNP) | VAF 33/167 reads (20%) | catalogued as COSV99245369; called by muse, mutect2, varscan2
- SPINK5 | c.1206G>T p.M402I | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs767288807, COSV99807238; called by muse, mutect2, varscan2
- SRCAP | c.6148G>T p.V2050L | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV99351138; called by muse, mutect2, varscan2
- SRCAP | c.9193C>T p.R3065C | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.764); catalogued as rs760273993, COSV99351145; called by muse, mutect2, varscan2
- SSX1 | c.261C>A p.D87E | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as COSV100976411; called by muse, mutect2, varscan2
- ST3GAL3 | c.844C>T p.P282S (on ENST00000361392 / NM_174964.4; = p.P267S on NM_006279.5) | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.83); PolyPhen benign (0.009); catalogued as COSV99495937; called by muse, mutect2, varscan2
- STAB2 | c.7598C>G p.P2533R | Missense Mutation (SNP) | VAF 26/185 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs765996605, COSV101186252; called by muse, mutect2, varscan2
- STAG3 | c.2600T>A p.L867Q | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100426150, COSV57927506; called by muse, mutect2, varscan2
- STARD3NL | c.400A>G p.S134G | Missense Mutation (SNP) | VAF 28/160 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as rs1483759753, COSV99151607; called by muse, mutect2, varscan2
- STING1 | c.268G>T p.G90C | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as rs1224811053, COSV100423484; called by muse, mutect2, varscan2
- STIP1 | c.213G>T p.W71C | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100534957; called by muse, mutect2
- STMN4 | c.523G>T p.E175* (on ENST00000265770 / NM_001283054.2; = p.E202* on NM_030795.4) | Nonsense Mutation (SNP) | VAF 5/18 reads (28%) | catalogued as rs1406578813, COSV56108668, COSV99740676; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.3203C>A p.T1068K | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV100562208; called by muse, mutect2, varscan2
- STRA8 | c.40C>A p.Q14K | Missense Mutation (SNP) | VAF 33/158 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99312618; called by muse, mutect2, varscan2
- STT3A | c.811T>C p.F271L | Missense Mutation (SNP) | VAF 9/175 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV101205273; called by muse, mutect2
- SUN1 | c.346G>A p.V116I (on ENST00000405266 / NM_001367651.1; = p.V66I on NM_025154.6 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as rs374613091; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYDE2 | c.826C>T p.H276Y | Missense Mutation (SNP) | VAF 22/140 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV99320607; called by muse, mutect2, varscan2
- SYTL5 | c.226G>T p.D76Y | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as COSV99937556; called by muse, mutect2, varscan2
- TAF1 | c.3508G>T p.V1170F (on ENST00000373790 / NM_138923.4; = p.V1191F on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/169 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99336792; called by muse, mutect2, varscan2
- TBCCD1 | c.777G>T p.W259C | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.159); catalogued as rs1240201476, COSV100112120; called by muse, mutect2, varscan2
- TBPL1 | c.445T>G p.L149V | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.186); catalogued as COSV99260462; called by muse, mutect2, varscan2
- TDRD5 | c.1147G>T p.E383* | Nonsense Mutation (SNP) | VAF 19/93 reads (20%) | catalogued as COSV99675315; called by muse, mutect2, varscan2
- TDRD6 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.133); catalogued as COSV100288209; called by muse, mutect2
- TDRD6 | c.1021G>T p.A341S | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100288210; called by muse, mutect2, varscan2
- TEDC2 | c.198A>G p.A66= | Splice Region (SNP) | VAF 10/34 reads (29%) | catalogued as COSV99564068; called by muse, mutect2, varscan2
- TENT4A | c.1021A>G p.K341E | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100049238; called by muse, mutect2, varscan2
- TENT5D | c.164G>T p.G55V | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as COSV100382919, COSV57635532; called by muse, mutect2, varscan2
- TEP1 | c.2924C>T p.S975F | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52996705; called by muse, mutect2, varscan2
- TEX11 | c.2416G>C p.E806Q (on ENST00000344304; = p.E791Q on NM_031276.3) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100722152; called by muse, mutect2, varscan2
- TEX13A | c.553G>C p.A185P | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV100781870; called by muse, mutect2, varscan2
- TEX13B | c.330C>A p.N110K | Missense Mutation (SNP) | VAF 29/250 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.553); catalogued as COSV100258484; called by muse, mutect2, varscan2
- THSD1 | c.1507C>A p.P503T | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV99319047; called by muse, mutect2, varscan2
- TIAM1 | c.3366+1G>T p.X1122_splice | Splice Site (SNP) | VAF 19/69 reads (28%) | catalogued as COSV99738314; called by muse, mutect2, varscan2
- TIMM8A | c.82C>A p.Q28K | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV100437852; called by muse, mutect2, varscan2
- TKTL1 | c.1106G>T p.R369L | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV54214171, COSV99474137; called by muse, mutect2
- TLE4 | c.118C>A p.Q40K | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.141); catalogued as rs1445119616, COSV99512955; called by muse, mutect2, varscan2
- TMC3 | c.2038A>T p.I680F | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as COSV100845992; called by muse, mutect2, varscan2
- TMEM132B | c.1255G>C p.V419L | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.105); catalogued as COSV100169719, COSV100170691; called by muse, mutect2, varscan2
- TMEM174 | c.61T>A p.Y21N | Missense Mutation (SNP) | VAF 39/175 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.775); catalogued as COSV99703803; called by muse, mutect2, varscan2
- TMEM190 | c.242T>G p.M81R | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.193); catalogued as COSV99404371; called by muse, mutect2, varscan2
- TMEM47 | c.429G>T p.L143F | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99327875; called by muse, mutect2, varscan2
- TMEM94 | c.1071G>T p.L357= | Splice Region (SNP) | VAF 16/45 reads (36%) | catalogued as rs769800453, COSV100050833; called by muse, mutect2, varscan2
- TMPRSS11B | c.562G>T p.G188* | Nonsense Mutation (SNP) | VAF 14/50 reads (28%) | catalogued as COSV100219494, COSV60293525; called by muse, mutect2, varscan2
- TMPRSS11F | c.148C>A p.H50N | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV100678761; called by muse, mutect2, varscan2
- TNFRSF19 | c.704G>T p.C235F | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1365338427, COSV99947689; called by muse, mutect2, varscan2
- TNFRSF25 | c.96G>C p.R32S | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as COSV100557091; called by muse, mutect2
- TNPO1 | c.1439A>C p.Q480P | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV100473889; called by muse, mutect2, varscan2
- TOP3B | c.427G>T p.G143C | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.612); catalogued as rs1488574727, COSV100592731; called by muse, mutect2, varscan2
- TPO | c.203T>A p.L68H | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.619); catalogued as rs1338916377, COSV100221887; called by muse, mutect2, varscan2
- TRBV28 | c.249C>A p.Y83* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as rs771003855; called by muse, mutect2, varscan2
- TRPC6 | c.568A>G p.K190E | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.77); PolyPhen benign (0.026); catalogued as rs779429635, COSV100723744; called by muse, mutect2, varscan2
- TRPM4 | c.1991G>T p.R664L | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.301); catalogued as COSV99420749; called by muse, mutect2, varscan2
- TSGA10IP | c.658C>A p.L220M | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.237); catalogued as COSV101598433; called by muse, mutect2, varscan2
- TSKS | c.1330T>C p.S444P | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99883635; called by muse, mutect2, varscan2
- TSPAN12 | c.199A>G p.M67V | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as rs1562950978, COSV99763329; called by muse, mutect2, varscan2
- TTBK1 | c.289G>T p.G97C | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99445439; called by muse, mutect2, varscan2
- TTC12 | c.1901A>G p.E634G | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.132); catalogued as COSV100133306; called by muse, mutect2, varscan2
- TTC7A | c.2564C>T p.P855L | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as COSV99766892, COSV99766972; called by muse, mutect2, varscan2
- TTK | c.984+1G>T p.X328_splice | Splice Site (SNP) | VAF 17/129 reads (13%) | catalogued as COSV100036551; called by muse, mutect2, varscan2
- TTN | c.86676T>A p.F28892L (on ENST00000591111; = p.F21468L on NM_003319.4) | Missense Mutation (SNP) | VAF 18/92 reads (20%) | PolyPhen benign (0.013); catalogued as COSV100626644; called by muse, mutect2, varscan2
- TTN | c.80872C>G p.R26958G (on ENST00000591111; = p.R19534G on NM_003319.4) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | PolyPhen probably damaging (0.998); catalogued as COSV100626645, COSV59879259; called by muse, mutect2, varscan2
- TTN | c.50908G>T p.V16970F (on ENST00000591111; = p.V9546F on NM_003319.4) | Missense Mutation (SNP) | VAF 21/86 reads (24%) | PolyPhen probably damaging (0.967); catalogued as COSV100626647; called by muse, mutect2, varscan2
- TTN | c.13742A>T p.Q4581L (on ENST00000591111; = p.Q3654L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/38 reads (24%) | PolyPhen benign (0.083); catalogued as COSV100626648; called by muse, mutect2, varscan2
- TTN | c.9882C>A p.Y3294* (on ENST00000591111; = p.Y3248* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 26/127 reads (20%) | catalogued as COSV100626649; called by muse, mutect2, varscan2
- TULP3 | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV101237595; called by muse, mutect2, varscan2
- TYK2 | c.3157G>A p.E1053K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.496); catalogued as rs752395240, COSV53384336; called by muse, mutect2, varscan2
- UBA1 | c.2213G>A p.G738E | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100256033; called by muse, mutect2, varscan2
- UBR1 | c.3799G>T p.D1267Y | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as rs1322889701, COSV99317741; called by muse, mutect2, varscan2
- UPP2 | c.848A>G p.D283G | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.225); catalogued as COSV99135179; called by muse, mutect2, varscan2
- UQCRQ | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV99737495; called by muse, mutect2, varscan2
- USF3 | c.3578C>A p.P1193Q | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.251); catalogued as rs779806841, COSV100325702; called by muse, mutect2, varscan2
- USP42 | c.639C>G p.C213W | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100084837, COSV60364175; called by muse, mutect2, varscan2
- USP51 | c.630C>A p.N210K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.186); catalogued as COSV101540693; called by muse, mutect2, varscan2
- USP8 | c.1972-2A>C p.X658_splice | Splice Site (SNP) | VAF 8/126 reads (6%) | catalogued as COSV100209240; called by muse, mutect2
- UTRN | c.9991A>G p.R3331G | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100838710; called by muse, mutect2, varscan2
- VCAM1 | c.464G>T p.G155V | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as COSV99658860; called by muse, mutect2, varscan2
- VCAN | c.7069C>A p.H2357N | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.053); catalogued as rs748853681, COSV99427066; called by muse, mutect2, varscan2
- VPS13B | c.1227G>T p.E409D | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.978); catalogued as COSV100663290; called by muse, mutect2, varscan2
- VPS35L | c.2399A>C p.E800A | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT tolerated (0.53); PolyPhen benign (0.013); catalogued as COSV99221574; called by muse, mutect2, varscan2
- WBP4 | c.716G>T p.G239V | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs767591716, COSV101069328; called by muse, mutect2
- WDR48 | c.493A>T p.S165C | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.905); catalogued as COSV100176883; called by muse, mutect2, varscan2
- WDR72 | c.116delinsTT p.G39Vfs*11 | Frame Shift Ins (INS) | VAF 29/131 reads (22%) | catalogued as COSV100854894; called by mutect2*, pindel, varscan2*
- WDSUB1 | c.1423C>G p.Q475E | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV99715004; called by muse, mutect2, varscan2
- WNK2 | c.5113C>A p.H1705N (on ENST00000297954 / NM_001282394.1; = p.H1668N on NM_006648.3) | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.116); catalogued as COSV99944216; called by muse, mutect2, varscan2
- WNT5B | c.176G>T p.R59M | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as COSV100148814; called by muse, mutect2, varscan2
- XIRP2 | c.541G>C p.E181Q (on ENST00000628543; = p.E356Q on NM_152381.6) | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54721206, COSV99746606; called by muse, mutect2, varscan2
- XKRX | c.55C>G p.L19V | Missense Mutation (SNP) | VAF 32/180 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100139791; called by muse, mutect2, varscan2
- XYLT2 | c.1405T>A p.C469S | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV99191070; called by muse, mutect2, varscan2
- YIPF3 | c.223G>T p.E75* | Nonsense Mutation (SNP) | VAF 23/85 reads (27%) | catalogued as COSV100397094; called by muse, mutect2, varscan2
- YPEL4 | c.302C>G p.A101G | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100254282; called by muse, mutect2, varscan2
- ZC3H14 | c.448G>T p.G150* | Nonsense Mutation (SNP) | VAF 23/77 reads (30%) | catalogued as COSV99193218; called by muse, mutect2, varscan2
- ZEB2 | c.169G>C p.D57H | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as rs1357146280, COSV100356712; called by muse, mutect2, varscan2
- ZIM2 | c.640T>A p.S214T | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.938); catalogued as COSV99690160; called by muse, mutect2, varscan2
- ZNF157 | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 9/94 reads (10%) | catalogued as COSV100998528; called by muse, mutect2
- ZNF160 | c.2101G>T p.G701* | Nonsense Mutation (SNP) | VAF 24/134 reads (18%) | catalogued as COSV100762456; called by muse, mutect2, varscan2
- ZNF181 | c.1499G>A p.C500Y | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101106421; called by muse, mutect2, varscan2
- ZNF214 | c.747C>G p.C249W | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs778949604, COSV99547617; called by muse, mutect2, varscan2
- ZNF229 | c.1513C>A p.Q505K | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.281); catalogued as rs376124482; called by muse, mutect2, varscan2
- ZNF300 | c.298T>C p.C100R | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.012); catalogued as COSV99200061; called by muse, mutect2, varscan2
- ZNF329 | c.28T>C p.F10L | Missense Mutation (SNP) | VAF 91/247 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100798813, COSV63771868; called by muse, mutect2, varscan2
- ZNF334 | c.1607A>G p.Q536R | Missense Mutation (SNP) | VAF 60/195 reads (31%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs1361267277, COSV100749182; called by muse, mutect2, varscan2
- ZNF383 | c.1024G>T p.E342* | Nonsense Mutation (SNP) | VAF 21/119 reads (18%) | catalogued as rs1193301319, COSV100776792; called by muse, mutect2, varscan2
- ZNF415 | c.1504G>T p.G502C | Missense Mutation (SNP) | VAF 50/230 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as COSV99701959; called by muse, mutect2, varscan2
- ZNF536 | c.167C>A p.P56H | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.681); catalogued as rs1314626917, COSV100834850, COSV100835743; called by muse, mutect2, varscan2
- ZNF536 | c.502G>C p.A168P | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV100835744; called by muse, mutect2, varscan2
- ZNF536 | c.2467G>C p.D823H | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV100834885, COSV100835746, COSV62824343; called by muse, mutect2, varscan2
- ZNF558 | c.162_163insT p.E55* | Frame Shift Ins (INS) | VAF 19/86 reads (22%) | catalogued as COSV100038022; called by mutect2, pindel, varscan2
- ZNF648 | c.1524G>C p.E508D | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.025); catalogued as rs759248474, COSV100374747; called by muse, mutect2, varscan2
- ZNF677 | c.947A>G p.E316G | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs1202362183, COSV100448138; called by muse, mutect2, varscan2
- ZNF804A | c.2202G>T p.Q734H | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV100167037, COSV100169824; called by muse, mutect2, varscan2
- ZNF804A | c.2801T>A p.L934H | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.436); catalogued as COSV100169825; called by muse, mutect2, varscan2
- ZNF804B | c.2395C>G p.R799G | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as COSV100305761; called by muse, mutect2, varscan2
- ZNF813 | c.907G>C p.E303Q | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.896); catalogued as COSV101124985; called by muse, mutect2, varscan2
- ZSWIM3 | c.715G>C p.V239L | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs889903504, COSV54852176, COSV99666914; called by muse, mutect2
- ZYG11B | c.2194C>T p.P732S | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.095); catalogued as rs1399903771, COSV99597756; called by muse, mutect2, varscan2
- ALG1 | c.245_246del p.R82Nfs*55 | Frame Shift Del (DEL) | VAF 10/77 reads (13%) | called by mutect2, pindel, varscan2
- ATP2A2 | c.1626_1627del p.K543Dfs*10 | Frame Shift Del (DEL) | VAF 3/26 reads (12%) | called by mutect2, pindel, varscan2
- BCL9L | c.2075del p.Q692Rfs*20 | Frame Shift Del (DEL) | VAF 5/34 reads (15%) | called by mutect2, pindel, varscan2
- CCDC117 | c.191_192del p.S64Cfs*4 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | called by mutect2, pindel, varscan2
- CFAP74 | c.1148C>A p.T383N | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- CNTNAP3 | c.3073A>T p.S1025C | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CPNE7 | c.1690del p.V564Sfs*81 | Frame Shift Del (DEL) | VAF 12/38 reads (32%) | called by mutect2, pindel, varscan2
- DCN | c.919G>T p.V307F | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); called by muse, mutect2
- DLG5 | c.1059_1060del p.E353Dfs*24 | Frame Shift Del (DEL) | VAF 12/112 reads (11%) | called by pindel, varscan2
- DNAJC25 | c.896_898del p.S299_L300delinsI | In Frame Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel, varscan2
- FBXO24 | c.841C>A p.Q281K (on ENST00000241071 / NM_033506.3; = p.Q319K on NM_012172.5) | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.22); called by muse, mutect2
- FMO3 | c.73_101del p.G25Qfs*2 | Frame Shift Del (DEL) | VAF 10/72 reads (14%) | called by mutect2, pindel
- FREM1 | c.1836dup p.V613Cfs*7 | Frame Shift Ins (INS) | VAF 7/32 reads (22%) | called by pindel, varscan2
- IGHV1OR15-9 | c.32T>A p.V11E | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- IGKV3D-20 | c.227C>A p.A76D | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- IL9R | c.925G>A p.A309T | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); called by mutect2, varscan2
- KCND1 | c.364G>T p.G122C | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRRC7 | c.3159del p.P1054Hfs*8 (on ENST00000651989 / NM_001370785.2; = p.P1021Hfs*8 on NM_001330635.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 7/40 reads (18%) | called by mutect2, pindel*
- NEU1 | c.616-1_616del p.X206_splice | Splice Site (DEL) | VAF 15/71 reads (21%) | called by mutect2, pindel, varscan2
- PIP4K2B | c.385A>T p.S129C | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- PKP4 | c.37G>T p.G13W | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2
- PLCH2 | c.552dup p.G185Rfs*37 | Frame Shift Ins (INS) | VAF 15/84 reads (18%) | called by mutect2, pindel, varscan2
- PROCR | c.515_516delinsT p.N172Ifs*56 | Frame Shift Del (DEL) | VAF 17/118 reads (14%) | called by pindel, varscan2*
- RUFY2 | c.608del p.G203Efs*4 | Frame Shift Del (DEL) | VAF 6/41 reads (15%) | called by mutect2, pindel, varscan2
- SATL1 | c.1213+1del p.X405_splice (on ENST00000395409; = p.X592_splice on NM_001012980.2) | Splice Site (DEL) | VAF 7/53 reads (13%) | called by mutect2, pindel
- SS18L2 | c.130G>T p.G44W | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- STAT1 | c.1375_1377del p.S459del | In Frame Del (DEL) | VAF 20/75 reads (27%) | called by mutect2, pindel, varscan2
- STK11 | c.157del p.D53Tfs*11 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | called by mutect2, pindel, varscan2
- SUPT20HL2 | c.765C>A p.D255E | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TECRL | c.154_157del p.V52Nfs*27 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | called by mutect2, pindel, varscan2
- TNFSF10 | c.332del p.S111Ffs*3 | Frame Shift Del (DEL) | VAF 14/82 reads (17%) | called by mutect2, pindel, varscan2
- TRAV3 | c.142G>A p.G48R | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TRDC | c.349A>G p.I117V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, varscan2
- UGT2B15 | c.192del p.N65Mfs*10 | Frame Shift Del (DEL) | VAF 83/243 reads (34%) | called by mutect2, varscan2
- WDR72 | c.117dup p.Q40Sfs*10 | Frame Shift Ins (INS) | VAF 28/104 reads (27%) | called by mutect2, varscan2
- ZNF263 | c.388-11_405del p.X130_splice | Splice Site (DEL) | VAF 9/41 reads (22%) | called by mutect2, pindel
- ZNF425 | c.702del p.R234Sfs*24 | Frame Shift Del (DEL) | VAF 10/92 reads (11%) | called by mutect2, pindel, varscan2
- ZNF605 | c.16-2A>G p.X6_splice | Splice Site (SNP) | VAF 8/57 reads (14%) | called by muse, mutect2, varscan2
- ABCC11 | c.852C>A p.T284= | Silent (SNP) | VAF 33/150 reads (22%) | catalogued as COSV100751092; called by muse, mutect2, varscan2
- ACR | c.72G>T p.T24= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV99334539; called by muse, mutect2, varscan2
- ADAMTS5 | c.310C>A p.R104= | Silent (SNP) | VAF 11/108 reads (10%) | catalogued as rs778769504, COSV99538227; called by muse, mutect2
- ADCY9 | c.3570C>T p.T1190= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as rs762725307, COSV99570750; called by muse, mutect2, varscan2
- AGPAT1 | c.237G>T p.L79= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as rs1440502864, COSV100421702; called by muse, mutect2, varscan2
- AHNAK2 | c.5835C>A p.P1945= | Silent (SNP) | VAF 45/288 reads (16%) | catalogued as COSV100318725, COSV60933431; called by muse, mutect2, varscan2
- ANKH | c.882G>T p.T294= | Silent (SNP) | VAF 22/112 reads (20%) | catalogued as COSV99415703; called by muse, mutect2, varscan2
- ANKRD33 | c.345G>T p.V115= (on ENST00000340970 / NM_001304459.2; = p.V240= on NM_182608.4) | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs1204903292, COSV100001296, COSV100001486; called by muse, mutect2, varscan2
- ANKRD55 | c.1200G>A p.Q400= | Silent (SNP) | VAF 31/211 reads (15%) | catalogued as COSV100591574; called by muse, mutect2, varscan2
- ARMH3 | c.2019C>T p.F673= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV99493571; called by muse, mutect2, varscan2
- ASL | c.645G>T p.L215= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as rs1480124074, COSV100508991; called by muse, mutect2, varscan2
- ASNS | c.1077G>T p.V359= | Silent (SNP) | VAF 14/97 reads (14%) | catalogued as rs1238954130, COSV99446710; called by muse, mutect2, varscan2
- ASXL3 | c.2724C>A p.I908= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV99326215; called by muse, mutect2, varscan2
- B3GALNT1 | c.36G>A p.R12= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100252151; called by muse, mutect2, varscan2
- BCL6 | c.969G>T p.L323= | Silent (SNP) | VAF 45/122 reads (37%) | catalogued as rs1339509097, COSV99215987; called by muse, mutect2, varscan2
- BDP1 | c.4200G>T p.G1400= | Silent (SNP) | VAF 14/86 reads (16%) | catalogued as rs1046216068, COSV100703448; called by muse, mutect2, varscan2
- BNC2 | c.705C>T p.I235= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs1284359352, COSV101034258; called by muse, mutect2, varscan2
- C3 | c.2944C>T p.L982= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV99837141; called by muse, mutect2, varscan2
- C6orf118 | c.249C>A p.A83= | Silent (SNP) | VAF 6/63 reads (10%) | catalogued as COSV100024989; called by muse, mutect2, varscan2
- C9 | c.240C>T p.D80= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as rs761782777, COSV54677511; called by muse, mutect2, varscan2
- CCKAR | c.1065C>T p.I355= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV55162464; called by muse, mutect2, varscan2
- CCNA1 | c.1015C>T p.L339= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as COSV55221283, COSV99714831; called by muse, mutect2, varscan2
- CD93 | c.759G>A p.S253= | Silent (SNP) | VAF 50/151 reads (33%) | catalogued as rs1038236217, COSV99849510; called by muse, mutect2, varscan2
- CFAP251 | c.1386C>G p.L462= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as rs11043266, COSV99996416; called by muse, mutect2, varscan2
- CIDEB | c.639G>A p.K213= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as rs1183896699, COSV99350624, COSV99351108; called by muse, mutect2, varscan2
- CNKSR3 | c.1149C>T p.S383= | Silent (SNP) | VAF 17/96 reads (18%) | catalogued as COSV70481437; called by muse, mutect2, varscan2
- COQ8B | c.480C>T p.L160= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as COSV99699586; called by muse, mutect2, varscan2
- CRYAB | c.522G>A p.K174= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV99909956; called by muse, mutect2, varscan2
- CSMD2 | c.7569C>A p.I2523= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV99584408, COSV99594407; called by muse, mutect2, varscan2
- CXorf65 | c.288T>A p.P96= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV99340396; called by muse, mutect2, varscan2
- CYP17A1 | c.909C>A p.G303= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as COSV100882137, COSV64004782; called by muse, mutect2, varscan2
- DGKA | c.372G>T p.T124= | Silent (SNP) | VAF 20/145 reads (14%) | catalogued as rs745363675, COSV100093354, COSV59384107; called by muse, mutect2, varscan2
- DICER1 | c.909A>G p.L303= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as rs773509809, COSV58618100; ClinVar: likely benign; called by muse, mutect2
- DISC1 | c.1722G>T p.L574= | Silent (SNP) | VAF 13/61 reads (21%) | catalogued as COSV99698466; called by muse, mutect2, varscan2
- DLGAP2 | c.2463A>T p.V821= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs200986859, COSV101422589; called by muse, mutect2, varscan2
- DNAH11 | c.13065C>A p.L4355= | Silent (SNP) | VAF 24/99 reads (24%) | catalogued as CD1110438, COSV100180482; called by muse, mutect2, varscan2
- DNAH3 | c.8145C>A p.A2715= | Silent (SNP) | VAF 41/177 reads (23%) | catalogued as COSV99770112; called by muse, mutect2, varscan2
- DOP1B | c.477C>T p.S159= | Silent (SNP) | VAF 6/69 reads (9%) | catalogued as rs1221582117, COSV99536008; called by muse, mutect2
- DPT | c.420A>T p.P140= | Silent (SNP) | VAF 12/45 reads (27%) | catalogued as COSV100892162; called by muse, mutect2, varscan2
- DPY19L1 | c.774T>G p.A258= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV100204935; called by muse, mutect2, varscan2
- DPYD | c.660A>G p.Q220= | Silent (SNP) | VAF 14/87 reads (16%) | catalogued as COSV100929324; called by muse, mutect2, varscan2
- DST | c.12327G>T p.T4109= (on ENST00000361203 / NM_001374722.1; = p.T1697= on NM_015548.5) | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs763102936, COSV99759295, COSV99759333; called by muse, mutect2, varscan2
- EIF1 | c.261T>C p.G87= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as COSV100179549; called by muse, mutect2, varscan2
- ELK1 | c.135G>T p.L45= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV55954549, COSV99902318; called by muse, mutect2, varscan2
- EXOC4 | c.1248A>T p.L416= | Silent (SNP) | VAF 39/178 reads (22%) | catalogued as COSV54098524, COSV99555347; called by muse, mutect2, varscan2
- F2R | c.1035C>A p.T345= | Silent (SNP) | VAF 19/95 reads (20%) | catalogued as COSV100058616; called by muse, mutect2, varscan2
- FAM160A2 | c.1533G>T p.L511= (on ENST00000449352 / NM_001098794.2; = p.L525= on NM_032127.4) | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV99792449; called by muse, mutect2, varscan2
- FAM47A | c.1368C>A p.T456= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs1197041466, COSV100650034, COSV60496461; called by muse, mutect2
- FAM47C | c.2274C>T p.R758= | Silent (SNP) | VAF 18/136 reads (13%) | catalogued as rs781979135, COSV63726405, COSV63729893; called by muse, mutect2, varscan2
- FAT2 | c.5751C>A p.T1917= | Silent (SNP) | VAF 26/109 reads (24%) | catalogued as rs745404172, COSV99943929; called by muse, mutect2, varscan2
- FAT2 | c.5004G>A p.E1668= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV99943930; called by muse, mutect2, varscan2
- FAT3 | c.7692A>G p.L2564= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV99970174; called by muse, mutect2, varscan2
- FCGBP | c.12432G>T p.G4144= | Silent (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2
- FCRL2 | c.819T>C p.Y273= | Silent (SNP) | VAF 25/107 reads (23%) | catalogued as rs536322468, COSV100829991, COSV63834073; called by muse, mutect2, varscan2
- FEZ1 | c.258C>A p.P86= | Silent (SNP) | VAF 12/100 reads (12%) | called by muse, mutect2, varscan2
- FRMPD3 | c.5067G>T p.L1689= | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV99346937; called by muse, mutect2, varscan2
- FSCB | c.1179C>A p.P393= | Silent (SNP) | VAF 26/113 reads (23%) | catalogued as rs1294360110, COSV100469768; called by muse, mutect2, varscan2
- GABRA6 | c.1185C>T p.P395= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as COSV99194923; called by muse, mutect2, varscan2
- GEMIN4 | c.2487G>A p.S829= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as rs751977516, COSV56745309; called by muse, mutect2, varscan2
- GFRA1 | c.588C>A p.L196= | Silent (SNP) | VAF 9/61 reads (15%) | catalogued as COSV100815654, COSV62605176; called by muse, mutect2, varscan2
- GHSR | c.210C>G p.R70= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as COSV99577163; called by muse, mutect2, varscan2
- GPR139 | c.501C>T p.P167= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV100430013; called by muse, mutect2, varscan2
- GPR6 | c.228C>T p.D76= | Silent (SNP) | VAF 21/147 reads (14%) | catalogued as COSV99254506; called by muse, mutect2, varscan2
- GRIK1 | c.1929C>A p.P643= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as COSV100517721; called by muse, mutect2
- GRM1 | c.2832G>T p.L944= | Silent (SNP) | VAF 22/156 reads (14%) | catalogued as COSV99268560; called by muse, mutect2, varscan2
- GRM8 | c.2508C>A p.P836= | Silent (SNP) | VAF 13/57 reads (23%) | catalogued as COSV100285472; called by muse, mutect2, varscan2
- HOXA11 | c.813C>G p.R271= | Silent (SNP) | VAF 19/119 reads (16%) | catalogued as COSV99136098; called by muse, mutect2, varscan2
- HRNR | c.6432T>C p.S2144= | Silent (SNP) | VAF 64/1907 reads (3%) | catalogued as COSV64254598; called by muse, mutect2
- HRNR | c.2208A>C p.S736= | Silent (SNP) | VAF 49/398 reads (12%) | catalogued as COSV100913863; called by muse, mutect2, varscan2
- HUWE1 | c.6780C>G p.P2260= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV99473923; called by muse, mutect2
- ICA1 | c.348A>C p.T116= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as COSV99655795; called by muse, mutect2, varscan2
- IDS | c.156C>G p.G52= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV100558168; called by muse, mutect2, varscan2
- IL17RC | c.702C>T p.F234= (on ENST00000295981 / NM_153461.4; = p.F163= on NM_032732.6 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 9/32 reads (28%) | catalogued as rs1311821159, COSV55966828; called by muse, mutect2, varscan2
- JADE2 | c.291C>T p.A97= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV99253590; called by muse, mutect2
- KCNG1 | c.1164C>T p.I388= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs370553196; called by muse, mutect2, varscan2
- KDM3B | c.942C>T p.S314= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as rs1344298640, COSV58687734; called by muse, mutect2, varscan2
- KIDINS220 | c.2079C>T p.L693= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as COSV99876310; called by muse, mutect2, varscan2
- KIF4A | c.3546C>A p.P1182= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV100978655; called by muse, mutect2, varscan2
- KLHL15 | c.441C>T p.I147= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as rs779509830, COSV60139807; called by muse, mutect2, varscan2
- KLK6 | c.348C>A p.A116= | Silent (SNP) | VAF 3/30 reads (10%) | catalogued as COSV100037824; called by muse, mutect2
- L1CAM | c.2109C>G p.V703= | Silent (SNP) | VAF 26/148 reads (18%) | catalogued as COSV100649433; called by muse, mutect2, varscan2
- LAMA1 | c.1863A>T p.T621= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as COSV101057495; called by muse, mutect2, varscan2
- LAMA5 | c.3600G>T p.V1200= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as rs1365640617, COSV99441885; called by mutect2, varscan2
- LLGL2 | c.1317C>T p.L439= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs1157714413, COSV99390390; called by muse, mutect2, varscan2
- LRP1B | c.9276T>A p.L3092= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as COSV101259993, COSV67239101; called by muse, mutect2, varscan2
- LYZL6 | c.90G>A p.V30= | Silent (SNP) | VAF 22/53 reads (42%) | called by muse, mutect2, varscan2
- MAFB | c.156C>A p.A52= | Silent (SNP) | VAF 15/65 reads (23%) | catalogued as COSV100965068; called by muse, mutect2, varscan2
- MAG | c.1860T>C p.Y620= | Silent (SNP) | VAF 11/41 reads (27%) | catalogued as COSV100728027; called by muse, mutect2, varscan2
- MAGEE1 | c.1137C>A p.S379= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV100819505, COSV63910022; called by muse, mutect2, varscan2
- MAN2A1 | c.2671A>C p.R891= | Silent (SNP) | VAF 7/78 reads (9%) | catalogued as COSV99811782; called by muse, mutect2
- MAN2B1 | c.1506G>T p.P502= | Silent (SNP) | VAF 4/17 reads (24%) | catalogued as COSV99667262; called by muse, mutect2, varscan2
- MAP7D3 | c.1521G>T p.L507= | Silent (SNP) | VAF 15/97 reads (15%) | catalogued as COSV100286622; called by muse, mutect2
- MCF2 | c.1728T>A p.P576= | Silent (SNP) | VAF 5/46 reads (11%) | called by mutect2, varscan2
- MDN1 | c.2076C>T p.H692= | Silent (SNP) | VAF 11/86 reads (13%) | catalogued as COSV101021752; called by muse, mutect2, varscan2
- MED24 | c.2913G>T p.T971= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as rs556276410, COSV99842532; called by muse, mutect2, varscan2
- MED28 | c.42C>A p.P14= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs377722370, COSV99403830; called by muse, mutect2, varscan2
- MOS | c.897C>A p.L299= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV100322982; called by muse, mutect2, varscan2
- MPDZ | c.1077A>T p.P359= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV100064298; called by muse, mutect2, varscan2
- MROH9 | c.1275G>T p.T425= | Silent (SNP) | VAF 11/78 reads (14%) | catalogued as rs752465494, COSV100883001, COSV63010198; called by muse, mutect2, varscan2
- MRPS5 | c.741G>C p.V247= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV99721016; called by muse, mutect2, varscan2
- MRTFB | c.237G>T p.A79= | Silent (SNP) | VAF 30/136 reads (22%) | catalogued as rs756700929, COSV100370810, COSV57956644; called by muse, mutect2, varscan2
- MSN | c.360G>A p.E120= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV100814292; called by muse, mutect2, varscan2
- MYH3 | c.3006G>A p.E1002= | Silent (SNP) | VAF 4/58 reads (7%) | catalogued as COSV99878741; called by muse, mutect2
- MYH7 | c.5040G>T p.L1680= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV100806512; called by muse, mutect2, varscan2
- MYO9A | c.4761A>G p.K1587= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV100614180; called by muse, mutect2, varscan2
- MYOF | c.2814G>A p.E938= | Silent (SNP) | VAF 28/90 reads (31%) | catalogued as rs769327487, COSV100826083; called by muse, mutect2, varscan2
- NBN | c.120G>T p.S40= | Silent (SNP) | VAF 21/130 reads (16%) | catalogued as rs774989816, COSV55373096, COSV99619967; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- NCKAP5 | c.1369C>T p.L457= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as rs1490068298, COSV58444905, COSV58445536; called by muse, mutect2, varscan2
- NEK5 | c.579C>G p.V193= | Silent (SNP) | VAF 16/120 reads (13%) | catalogued as COSV100839290; called by muse, mutect2, varscan2
- NIM1K | c.426C>T p.T142= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as COSV100390395; called by muse, mutect2
- NLGN4X | c.892C>A p.R298= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as COSV99321935; called by muse, mutect2, varscan2
- NOXRED1 | c.1077A>G p.Q359= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV53628677; called by muse, mutect2
96 further variants in this file (0 protein-altering or splice-affecting, 73 silent, 23 other) are not listed here.
